MMRF case MMRF_1733 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7bec9473-a475-446e-a275-ad55590d3644

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.6 years (18,496 days); ISS stage: I; Days to last known disease status: 1,108 days (3.0 years); Days to last follow up: 1,108 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 19 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 19 days.
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 37 days; Days to treatment end: 336 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 37 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 336 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days; Days to treatment end: 420 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Immunoglobulin G 33.5 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 8.2 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 0.038 mg/dL.
- Day 92 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 4.22 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.57 mmol/L.
- Day 176 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 2.85 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 5.3 g/dL; Glucose 3.03 mmol/L.
- Day 274 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 2.53 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 4.13 mmol/L.
- Day 358 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 3.63 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 5.6 g/dL; Glucose 4.02 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 2.05 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 4.35 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 7.12 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 355 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.46 mmol/L.
- Day 624 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 6.61 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 3.85 mmol/L.
- Day 708 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 4.46 mmol/L.
- Day 799 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 7.03 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 890 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.4 mmol/L.
- Day 995 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 7.26 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 3.69 mmol/L.
- Day 1,108 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 7.72 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7.5 g/dL; Glucose 4.07 mmol/L.

Other clinical attributes
- Day -13: Weight: 62 kg; Height: 178 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1733_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1733_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
